Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACNN, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACNN-TTP1-A (Primary Tumor).

Submissions:

- a) Hilar lymph node lobar, removal
- b) Lymph node right upper lobar bronchus, removal
- c) Right upper lobe, removal
- d) Lymph node lower lobe, removal
- e) Para esophageal mediastinal lymph nodes, removal

CDDP-YP-ACNN-01-PR

**Macroscopic report:**

- a) A blackish fragment of cm 1.1 of major axis
- b) Un lymph node of cm 1.7 of major axis
- c) Right upper lung lobe of cm 17x11x15 (gr.144), with focally opaque serous in correspondence of whitish intra parenchymal neoplasm, neoplasm with polycyclic margins, of cm 3.4 of major axis, cm 1.5 away from the bronchial resection margin. The remaining parenchyma appears markedly congested, with focal areas of increased consistency.
Isolate 10 peribronchial lymph nodes
(C1 margin of broncho - vascular resection; C2 peribronchial lymph nodes ; C3 neoplasm; C4 neoplasm pleura; C5 neoplasm parenchyma in the sur rounding area; C6 parenchyma at a distance; C7-8 areas of consistency modestly increased)
- d) Six blackish fragments of major axis between cm 0.3 e cm 0.8
- e) Two lymph nodes of cm 0.8 e cm 0.9 of major axis.

Histopathologic diagnosis:

A-E) mixed lung adenocarcinoma (WHO 1999), acinar and papillary , medium degree of differentiation (G2); the neoplasm infiltrates the connective sub mesothelial visceral pleura, which does not appears however, exceeded.

Absence of angiolymphatic and perineural invasion.

Margin of bronchial and vascular resection free from neoplastic localization.

Emphysema in the remaining lung parenchyma , associated with focal areas of atelectasis with fibrotic septal thickening .

Anthraxis and sinus histiocytosis in the lymph nodes examined, free of neoplasia.

Staging pTNM: pT 2, N0

Codici SNOMED:

T-C4320	M-43000
T-C4000	M-43000
T-28200	M-81403
T-C4360	M-43000

ICD-0-3
adenocarcinoma with mixed subtypes 8255/3

Site
(R) lung, upper lobe C34.1

ICD-10
C34.11

W
10/13/16

Site Discrepancy		☒

Source: NCI Genomic Data Commons file 1dcdb8bb-aba9-465b-96ab-aad8f4631047 (CDDP-ACNN-TTP1.98D41ADD-1EF1-45EE-A541-2FCC5A83C893.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).